Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A2B8, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A2B8-01A (Primary Tumor).

Sex: Female
D.O.B.:

SPECIMEN INFORMATION

Collected
Received
Reported:

Accession #
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right axillary sentinel lymph node:
One lymph node, no evidence of metastatic carcinoma.
Confirms frozen section diagnosis and confirmed by negative staining for pancytokeratin.

B. Right breast mastectomy:

Residual invasive lobular carcinoma.
Size: 8 cm.
Architectural score: 3 of 3.
Nuclear score: 2 of 3.
Mitotic score: 1 of 3.
Total score: 6 of 9 = grade 2
Carcinoma involves portions of the nipple.
No evidence of involvement of the overlying epidermis.
Deep margin of excision is free of carcinoma.

HPA Discrepancy		X
Reviewed/initials	LM 5/27/11	5/11/11

pTNM classification: T3pN0 (-) MX.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right modified radical mastectomy with sentinel node mapping with frozen section. Invasive lobular carcinoma. ER positive, PR positive, Ki-67 (MIB1) high - 28%.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

1CD-0-3

Carcinoma: infiltrating lobular, nos 8520/3

Site: breast, nos C50.9

LM 5/27/11

SPECIMENS:

- A. Right axillary sentinel node #1300 with frozen section
B. Right breast

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two containers, labeled with the patient's name,

Container A is additionally labeled "right axillary sentinel node," and contains a 2.0 cm, yellow-tan, firm, fatty nodule. It is bisected and entirely submitted for frozen section. The residual is entirely resubmitted for permanent section in cassette A, labeled.

Container B is received with formalin, additionally labeled "right breast," and contains an 685.4 gm, 19.0 x 13.5 x 7.5 cm, simple mastectomy specimen, partially surfaced by a 17.0 x 8.0 cm ellipse of pink-tan wrinkled skin, bearing a central 0.9 x 0.9 x 0.5 cm inverted nipple. The deep margin is inked and the specimen is serially sectioned to reveal a 8.0 x 4.0 x 2.5 cm, ill-defined, gray-white gritty mass that resides 2.0 cm from the deep margin and 2.5 cm below the skin surface. The remainder of the cut surface is comprised of yellow-tan adipose tissue admixed with moderate amount of intermedium gray-white fibrous tissue. Additional masses are not identified. Representative sections are submitted in cassettes B1-11, labeled designated as follows: 1 - nipple; 2 - inked deep margin, perpendicular; 3-8 - mass; 9-11 - sections from the three uninvolved quadrants.

Additionally a yellow and green cassette are submitted for genomics research, each labeled

INTRA-OPERATIVE CONSULTATION:

- A. FROZEN SECTION DIAGNOSIS: "Negative for tumor," per Dr

The sentinel node contains two small microscopic glands in the outer layer of the fibrous capsule of the node. I think they are benign glandular inclusions. They stain with cytokeratin but they do not look like the invasive lobular carcinoma cells.

Source: NCI Genomic Data Commons file 86348139-e689-4a87-ae0b-cbc40ff8fe45 (TCGA-AC-A2B8.3D878253-22B3-4A53-AE54-C0D95E085DB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).